Somatic mutation profile of tumor specimen 0DX4FN from CCDI case PBCJAS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 10.8 years (3,951 days).
Specimen 0DX4FN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cb3bdbe-6651-4e47-a5f5-48089fbc2045.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX4EP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53630f1b-c157-4250-b742-993175e3ca2a

The open-access MAF lists 35 somatic variants for this specimen: 17 protein-altering or splice-affecting, 8 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Intron 8, Silent 8, Splice Site 2, 5'UTR 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR7A2 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 90/658 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs1362573068; called by muse, mutect2, varscan2
- DDX31 | c.1339del p.D447Tfs*7 | Frame Shift Del (DEL) | VAF 152/755 reads (20%) | catalogued as COSV60137709; called by mutect2, varscan2
- GPR162 | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 104/564 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV50592226; called by muse, mutect2, varscan2
- KLK5 | c.742C>G p.P248A | Missense Mutation (SNP) | VAF 61/371 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs990986894; called by muse, mutect2, varscan2
- TGFB1I1 | c.1303C>G p.L435V (on ENST00000394863 / NM_001042454.3; = p.L418V on NM_015927.4) | Missense Mutation (SNP) | VAF 90/439 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs1160562333, COSV62358353; called by muse, mutect2, varscan2
- AQP10 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 82/453 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDADC1 | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 136/642 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GIGYF2 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 96/659 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 33/1000 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- IL33 | c.715T>C p.F239L | Missense Mutation (SNP) | VAF 117/593 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- NWD2 | c.2087G>T p.R696I | Missense Mutation (SNP) | VAF 183/831 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OGT | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 165/413 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRR30 | c.935T>A p.L312Q | Missense Mutation (SNP) | VAF 97/423 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTGER3 | c.1104+1G>T p.X368_splice | Splice Site (SNP) | VAF 64/470 reads (14%) | called by muse, mutect2, varscan2
- PTGER3 | c.1104A>T p.Q368H | Missense Mutation (SNP) | VAF 63/465 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC7A9 | c.194G>C p.C65S | Missense Mutation (SNP) | VAF 129/609 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TBC1D19 | c.703+1G>T p.X235_splice | Splice Site (SNP) | VAF 43/218 reads (20%) | called by muse, mutect2, varscan2
- APBB1IP | c.891C>T p.S297= | Silent (SNP) | VAF 24/746 reads (3%) | called by muse, mutect2
- ARHGAP1 | c.1266C>T p.F422= | Silent (SNP) | VAF 128/523 reads (24%) | called by muse, mutect2, varscan2
- CSPG4 | c.1305C>T p.S435= | Silent (SNP) | VAF 53/496 reads (11%) | catalogued as COSV57892550; called by muse, mutect2, varscan2
- GPR162 | c.411C>A p.A137= | Silent (SNP) | VAF 104/567 reads (18%) | catalogued as rs146153056, COSV50589809; called by muse, mutect2, varscan2
- PAPLN | c.2535C>G p.A845= (on ENST00000554301; = p.A818= on NM_173462.4) | Silent (SNP) | VAF 74/322 reads (23%) | called by muse, mutect2, varscan2
- PLCG2 | c.2205G>C p.V735= | Silent (SNP) | VAF 139/744 reads (19%) | called by muse, mutect2, varscan2
- RNF216 | c.1689C>T p.S563= (on ENST00000425013 / NM_207116.3; = p.S620= on NM_207111.4) | Silent (SNP) | VAF 162/745 reads (22%) | called by muse, mutect2, varscan2
- SLIT1 | c.3318C>T p.S1106= | Silent (SNP) | VAF 92/438 reads (21%) | catalogued as COSV56590382; called by muse, mutect2, varscan2
- ATG16L2 | c.887+82C>A | Intron (SNP) | VAF 26/129 reads (20%) | called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 32/719 reads (4%) | called by muse, mutect2
- BTN3A3 | c.965-57G>A | Intron (SNP) | VAF 46/179 reads (26%) | called by muse, mutect2, varscan2
- CFP | c.227+23G>A | Intron (SNP) | VAF 74/134 reads (55%) | called by mutect2, varscan2
- ESCO2 | c.861+78A>G | Intron (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- FLII | c.3504-16G>T | Intron (SNP) | VAF 71/340 reads (21%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+2122T>A | Intron (SNP) | VAF 109/474 reads (23%) | called by muse, mutect2, varscan2
- PDE4C | c.596-38G>A | Intron (SNP) | VAF 16/73 reads (22%) | catalogued as rs1454860617; called by mutect2, varscan2
- PLCB1 | c.3423+11887G>A | Intron (SNP) | VAF 200/1058 reads (19%) | catalogued as rs962451898; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 22/180 reads (12%) | called by muse, varscan2
